TCGA case TCGA-WB-A81E — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Heart, mediastinum, and pleura; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ba65b478-65d0-4c9a-a2c2-d32b29a1a9c4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 47 years; Vital status: Alive.

Diagnoses (4)
1. Extra-adrenal paraganglioma, malignant (the primary disease): ICD-O-3 morphology code: 8693/3; ICD-10 code: C38.3; Tissue or organ of origin: Mediastinum, NOS; Site of resection or biopsy: Mediastinum, NOS; Classification of tumor: primary; Age at diagnosis: 47.7 years (17,407 days); Year of diagnosis: 2011; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 1,476 days (4.0 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 1,252 days (3.4 years); Days to treatment end: 1,468 days (4.0 years); Treatment dose: 600 mCi; Treatment outcome: Stable Disease; Number of fractions: 3; Treatment anatomic sites: Distant Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Gastrointestinal stromal tumor, NOS: ICD-O-3 morphology code: 8936/1; Tissue or organ of origin: Gastrointestinal tract, NOS; Classification of tumor: Prior primary; Age at diagnosis: 47.6 years (17,391 days); Days to diagnosis: -16 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 0 days; Treatment anatomic sites: Chest.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Metastasis of diagnosis 1 (Extra-adrenal paraganglioma, malignant), site: Bone, NOS. Prior treatment: Yes.
4. Recurrence of diagnosis 1 (Extra-adrenal paraganglioma, malignant), site: Lymph node, NOS. Age at diagnosis: 50.1 years (18,294 days); Days to diagnosis: 887 days (2.4 years); Prior treatment: Yes.

Follow-up (6 entries)
- Day 0 (prior to diagnosis): History of tumor: No; History of tumor type: Phenochromocytoma or Paraganglioma.
- Day 887 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 887 days (2.4 years); Evidence of recurrence type: Histologic Confirmation.
- Days to follow up: 1,131 days (3.1 years); Disease response: Tumor Free.
- Days to follow up: 1,476 days (4.0 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Other.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WB-A81E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 50 mg.
  Slide TCGA-WB-A81E-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WB-A81E-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WB-A81E-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Primary pathology: Submitted tumor site: Extra-adrenal Site; Site of primary tumor other: thoracic (mediastinal) paraganglioma; Related tumors outside adrenal glands: Single tumor outside the adrenal glands; Histologic diagnosis: Paraganglioma, Extra-adrenal Pheochromocytoma; Disease detected on screening: No; Ct scan preop results: Yes; Lymph nodes examined: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Gastrointestinal tract; Other malignancy histological type: Gastrointestinal Stromal Tumor.
- Other malignancy form, Surgery: Other malignancy surgery type: median sterniotomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,476 days; disease-specific survival: no event (censored), 1,476 days; disease-free interval: event (new tumor event after initially disease-free), 887 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 887 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WB-A81E-01A-11D-A35H-01): tumor purity 0.79, ploidy 1.87, whole-genome doublings 0.
